Somatic mutation profile of tumor specimen TCGA-FY-A3W9-01A (aliquot TCGA-FY-A3W9-01A-11D-A22D-08) from TCGA case TCGA-FY-A3W9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 66.1 years (24,136 days).
Specimen TCGA-FY-A3W9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60ec352e-23c8-4151-8de6-7a53c0274cae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3W9-10A (Blood Derived Normal), aliquot TCGA-FY-A3W9-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d99d216-a526-488d-a7d9-dfff5e962996

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 88/193 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1550G>A p.C517Y | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51090287; called by muse, mutect2, varscan2
- CA13 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58797866; called by muse, mutect2, varscan2
- CALCB | c.100A>G p.S34G | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV60834696; called by muse, mutect2, varscan2
- COL6A3 | c.3770G>A p.R1257K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs776473177, COSV55099591; called by mutect2, varscan2
- CRISP2 | c.493T>A p.Y165N | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59255823; called by muse, mutect2, varscan2
- CYB5R4 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV63751514; called by muse, mutect2, varscan2
- DDX4 | c.1384A>T p.K462* | Nonsense Mutation (SNP) | VAF 39/79 reads (49%) | catalogued as COSV61756192; called by muse, mutect2
- ESCO2 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs1485828431, COSV59415588; called by muse, mutect2, varscan2
- HBS1L | c.1969A>G p.K657E | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV63202087; called by muse, mutect2
- ICE1 | c.2924C>T p.A975V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV56824162; called by muse, mutect2, varscan2
- KIF4B | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1020996527, COSV70530509; called by muse, mutect2, varscan2
- SACS | c.13061A>T p.H4354L | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66544131; called by muse, mutect2, varscan2
- KDM2A | c.1045del p.H349Tfs*2 | Frame Shift Del (DEL) | VAF 56/156 reads (36%) | called by mutect2, pindel, varscan2
- CHRM3 | c.855C>A p.G285= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV55096154; called by muse, mutect2, varscan2
- CNGA3 | c.441G>A p.T147= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs754767905, COSV55626124; called by muse, mutect2, varscan2
- FAM217A | c.684A>G p.P228= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as COSV51161439; called by muse, mutect2
- FBXO44 | c.588G>A p.A196= | Silent (SNP) | VAF 62/111 reads (56%) | catalogued as rs367623463, COSV99278714; called by muse, mutect2, varscan2
- PHGDH | c.1491G>T p.A497= (on ENST00000369409; = p.R491L on NM_006623.4) | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV65568609; called by muse, mutect2
- SPHK1 | c.960A>G p.V320= (on ENST00000392496 / NM_001355139.2; = p.V334= on NM_021972.4) | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs771290002, COSV60065651; called by muse, mutect2, varscan2
